Gene-level copy-number profile of tumor specimen C3L-02968-02 from CPTAC case C3L-02968, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.8 years (23,682 days).
Specimen C3L-02968-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 61895bc8-22ba-4013-b014-9013d07fefc9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02968-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,789 have no estimate.
https://portal.gdc.cancer.gov/files/01710e23-ac37-46ac-935f-5497d3a59cab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 246; copy number 1: 20,987; copy number 2: 32,774; copy number 3: 2,918; copy number 4: 1,595; copy number 5: 14; copy number 6: 10; copy number 7: 47; copy number 8: 37; copy number 9: 53; copy number 10: 25; copy number 11: 31; copy number 12: 53; copy number 13: 4; copy number 14: 2; copy number 27: 6; copy number 28: 10; copy number 29: 3; copy number 30: 3; copy number 31: 7; copy number 42: 2; copy number 43: 5; copy number 46: 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:97,737,894–97,738,913, 1 gene: AC112203.1.
- chr9:30,388,935–30,575,012, 2 genes: LINC01242, SLC4A1APP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 288 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,249,522–168,830,599, 1 gene, copy number 12 (within-gene range 2–12): EGFEM1P.
- chr3:168,551,854–183,684,519, 240 genes, copy number 5–46 (broad region; genes not listed).
- chr8:38,099,471–39,284,917, 38 genes, copy number 7: AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10.
- chr9:39,734,670–39,741,193, 2 genes, copy number 9: RAB28P1, RBPJP5.
- chr17:40,792,196–40,885,242, 7 genes, copy number 6: KRT28, AC090283.1, KRT10, TMEM99, AC004231.4, KRT12, KRT20.

Autosomal genes at a single copy (total copy number 1): 18,691. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
